Surgical pathology report (de-identified scan), TCGA case TCGA-EA-A78R, project TCGA-CESC (Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma), tissue source site Asterand, specimen TCGA-EA-A78R-01A (Primary Tumor).

Patient ID:

Surgical Date:

Gross Description: Tumor is located and limited in cervix. It is protruded occupying lumen, with 4x3.5x3.5cm in size, soft and white-gray surface.

Microscopic Description: Squamous cell are hyperplastic to replace normal squamous cells and infiltrates in muscle propria. Tumor tissue arranges in the form of group or broad sheets or trabecular of tumor cells. The malignant cells have abundant, light eosinophilic cytoplasm. The nuclei are fairly enlarged, variability in size and shape, containing coarse clumped chromatin with prominent nucleoli. Mitotic figures are present. Stroma is invasion of lymphocytes.

Diagnosis Details: Squamous cell carcinoma, Grade II, infiltrating complete muscle propria

Comments:

Formatted Path Reports: CERVIX TISSUE CHECKLIST

Specimen type: Hysterectomy

Tumor site: Cervix

Tumor size: 4 x 3.5 x 3.5 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Lesion less than 4.0 cm

Lymph nodes: Not specified

Lymphatic invasion: Present

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3
Carcinoma, squamous cell
8070/3
Site Cervix NOS
539
JA 8/21/13

Case (Circle):		

hw 8/16/13
8/16/13

Source: NCI Genomic Data Commons file 76d265da-3387-48d9-8f2e-39fe0f026496 (TCGA-EA-A78R.36A90083-5078-435F-B9C2-337B75807716.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).